Surgical pathology report (de-identified scan), TCGA case TCGA-CZ-4860, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Harvard, specimen TCGA-CZ-4860-01A (Primary Tumor).

[page 1 of 4]
Accession Number: [REDACTED] Report Status: Amend/Addend
Type: Surgical Pathology
Specimen Type: Kidney, partial or total resection
Procedure Date:
Ordering Provider: [REDACTED]

CASE: [REDACTED]
PATIENT: [REDACTED]

***** Extended Report *****
Resident: [REDACTED]
Pathologist: [REDACTED]

CGA-CZ-4860

PATHOLOGIC DIAGNOSIS:

SPECIMEN LABELED "1. RIGHT KIDNEY":

RENAL CELL CARCINOMA (14.4 cm), Clear cell type, with rhabdoid features,
Fuhrman nuclear grade IV/IV.
Tumor invades the perinephric fat and renal pelvis.
Vascular (venous) and perineural invasion are identified.
Ureteral and arterial margins are free of tumor.
Renal vein could not be identified in the specimen.
Non-neoplastic kidney will be reviewed and reported in an addendum by
Renal Pathology.

AJCC stage = T4 Nx Mx

Immunohistochemistry performed at BWH demonstrates the following
staining profile in tumor cells:
Positive ? RCC; EMA

SPECIMEN LABELED "2. VENA CAVA TUMOR THROMBUS":
METASTATIC RENAL CELL CARCINOMA.

CLINICAL DATA:

History: None given.
Operation: Right radical nephrectomy
Operative Findings: None given.
Clinical Diagnosis: Right renal mass.

TISSUE SUBMITTED:

A/1. Right kidney with tumor (take to Pathology for Tissue Bank).
B/2. Vena caval tumor thrombus.

GROSS DESCRIPTION:

The specimen is received fresh, in two parts, each labeled with the patient's name and unit number.

Part A, "R kidney", consists of a 1072 gram mass, encased in peritoneum (19 x 10 x 0.9 cm) with an exposed portion of ? renal artery (0.6 cm in length x 0.5 cm in diameter) and possible urethral stump (0.1 cm in length x 1.9 cm in diameter). The urethral (?) stump is thick and appears completely involved by tumor (note: this might be vein, but impossible to tell). The urethral margin is inked blue. The arterial margin (?) is taken en face and inked orange. The mass is bisected along the possible ureter to reveal a yellow/white, lobulated, slightly hemorrhagic solid mass (14.4 x 9.6 x 7.0 cm) occupying most of the kidney. There is very little visible normal renal cortex and no distinct cortical medullary junction. The mass extends to the urethral resection margin and abuts the renal capsule but does appear to extend into the fat (there is a thin 0.8 cm rim of fat surrounding the kidney). There is a cystic cavity (1.0 x 1.0 x 0.9 cm) within the tumor. Six sections of the tumor are submitted to Tumor Bank as T1-T6. Half of T1 is also sent for [REDACTED] A section of the normal cortex is sent for Tumor Bank and Electron Microscopy. Normal medulla (?) is sent to Tumor Bank. Photographs are taken.

Micro A1: T1 Quickfix, 1 frag, [REDACTED]
Micro A2: Arterial margin (?), 1 frag, [REDACTED]
Micro A3: Urethral vs vascular (?) margin, 1 frag, [REDACTED]
Micro A4-A5: Tumor invasion into urethra vs vasculature (?), bisected, 2 frags, [REDACTED]
Micro A6: Tumor invading into ? vessel and soft tissue margin (inked blue), 1

[page 2 of 4]
Pathology Report

frag [REDACTED]

Micro A7-A8: Tumor invading into arterial margin (?), bisected, 2 frags, [REDACTED]

Micro A9: Tumor and capsule and perirenal fat, 1 frag, [REDACTED]

Micro A10: Tumor and adjacent normal kidney, 1 frag, [REDACTED]

Micro A11: Normal kidney, 1 frag, [REDACTED]

Part B, "#2 Vena caval tumor thrombus", consists of a tumor mass (3.2 x 1.5 x 1.5 cm) with attached fibrovascular tissue (2.8 x 1.2 x 0.5 cm). The possible fibrovascular tissue is inked black.

Micro B1-B2: Vena caval tumor thrombus, 2 frags, [REDACTED]

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

Resident Review by [REDACTED]

Final Diagnosis by [REDACTED]

ADDENDUM

RENAL PATHOLOGY EVALUATION OF NON-NEOPLASTIC KIDNEY PARENCHYMA [REDACTED]

RIGHT KIDNEY, NEPHRECTOMY:

DIFFUSE INTERSTITIAL FIBROSIS AND TUBULAR ATROPHY, MOST LIKELY SECONDARY TO CHRONIC OBSTRUCTIVE UROPATHY AND POSSIBLY VENOUS OBSTRUCTION (SEE NOTE)

ARTERIAL AND HYALINE ARTERIOLAR SCLEROSIS, MODERATE (SEE NOTE)

NOTE:

Only minimal non-neoplastic kidney parenchyma was available for examination due to the extensive replacement of nephrons by the neoplastic process. The sample of non-neoplastic kidney parenchyma examined showed diffuse parenchymal scarring and moderate vascular sclerosis, but only mild glomerulosclerosis. These changes are most likely the result of chronic ipsilateral collecting system obstruction, with a possible contribution by venous obstruction from the renal vein and inferior vena cava tumor thrombus. If the collecting system and vascular obstruction were only unilateral, only functional adaptive changes (and not the extensive parenchymal scarring seen here) would be expected in the contralateral kidney. Changes of diabetic glomerulosclerosis are not apparent in this sample. A potential effect of this patient's remote organochlorine exposure is not apparent in the tissue but is also unknown.

The kidney parenchyma has been reviewed by Dr. [REDACTED] Renal Pathologist.

MICROSCOPIC DESCRIPTION:

Sections of formalin-fixed, paraffin-embedded tissue (block A11) were evaluated using HE, PAS, Jones silver methenamine, and AFOG (trichrome) stains.

The sample consists of kidney cortex and medulla. There are eighty-one glomeruli present, of which six (7.4%) are globally sclerosed. The remaining glomeruli show hypoperfusion and only minimal and focal expansion of the mesangial areas. There are only rare discernible craters and double contours of the glomerular capillary wall basement membranes. Few distal tubules contain PAS-positive hyaline casts. Tubules show a reduction in size but there is only focal thickening of the basement membranes. Several tubules (block A10) show microcystic changes resembling thyroidization of the cortical parenchyma. The interstitium is diffusely expanded and appears markedly fibrotic without prominent inflammatory activity. Over 90% of the cortical parenchyma shows tubular atrophy and interstitial fibrosis. Arteries exhibit a moderate degree of sclerosis with some foam cell accumulation. Arterioles show moderate sclerosis with focal and segmental hyaline degeneration.

[page 3 of 4]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[page 4 of 4]
Accession Number: [REDACTED]
Type: Cytogenetics
CASE: [REDACTED]
PATIENT: [REDACTED]
Cytogeneticist: [REDACTED]

Report Status

KARYOTYPE: 46,XY[10]

METAPHASES COUNTED: 10

ANALYZED: 3

SCORED: 15

BANDING: GTG

INTERPRETATION:

5 of 15 metaphase cells were aneuploid, containing 118-126 chromosomes, but the chromosome morphology in these cells was very poor, and detailed cytogenetic analyses could not be performed. The remaining 10 metaphase cells were normal.

COMMENTS:

Mosaicism and small chromosome anomalies may not be detectable using the standard methods employed. Chromosome analysis was performed at a level of 400 bands or greater.

INDICATION FOR TEST:

RCC

Source: NCI Genomic Data Commons file b1a3d0dd-07a8-43ce-a150-09361e0052d2 (TCGA-CZ-4860.A19C8A6E-471A-4BB8-8BFC-EE319D064794.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).